Gene-level copy-number profile of tumor specimen C3L-06091-03 from CPTAC case C3L-06091, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 45.9 years (16,759 days).
Specimen C3L-06091-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4470ff1a-4fdc-42ca-aa40-8d3a15195e07.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06091-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/0c1e4643-66b0-4992-a50b-fc5643383ca0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 98; copy number 1: 7,416; copy number 2: 46,683; copy number 3: 4,206; copy number 4: 1.

Homozygous deletions (total copy number 0; autosomes only): 98 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:237,966,827–239,402,364, 35 genes: UBE2F, UBE2F-SCLY, RNU6-1333P, SCLY, ESPNL, KLHL30, KLHL30-AS1, ERFE, ILKAP, LINC02610, AC012485.1, HES6, PER2, AC012485.3, AC012485.2, TRAF3IP1, RNU6-234P, ASB1, AC016999.1, AC016999.2, LINC01107, LINC01937, AC113618.2, AC113618.1, AC145625.1, TWIST2, LINC01940, HDAC4, MIR4440, MIR4441, AC017028.1, AC017028.2, MIR4269, MIR2467, HDAC4-AS1.
- chr4:184,072,403–184,474,550, 11 genes (within-gene range 0–1): AC107222.1, ENPP6, AC107222.2, AC079080.1, RN7SL28P, MYL12BP2, LINC02363, LINC02362, IRF2, SNORD79, AC099343.2.
- chr9:21,186,694–22,029,594, 39 genes (within-gene range 0–1): IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr10:87,504,875–87,971,930, 13 genes (within-gene range 0–1): MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 7,416. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
